Somatic mutation profile of tumor specimen MP2PRT-PANCZY-TMP1-A (aliquot MP2PRT-PANCZY-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANCZY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.8 years (5,789 days).
Specimen MP2PRT-PANCZY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d8f559d-01c3-4f75-8cc9-13fb68408779.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANCZY-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANCZY-NM1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c618ae4-07be-4ee7-8109-273a506b8c3f

The open-access MAF lists 50 somatic variants for this specimen: 39 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 8, Nonsense Mutation 4, Frame Shift Ins 3, Intron 2, In Frame Ins 1, RNA 1, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK3 | c.4598C>G p.S1533* | Nonsense Mutation (SNP) | VAF 46/288 reads (16%) | catalogued as COSV55073878; called by muse, mutect2, varscan2
- ANXA1 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 139/320 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144842081; called by muse, mutect2, varscan2
- CPS1 | c.1003C>T p.Q335* | Nonsense Mutation (SNP) | VAF 71/466 reads (15%) | catalogued as COSV51802255; called by muse, mutect2
- CUL1 | c.344T>C p.V115A | Missense Mutation (SNP) | VAF 41/320 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs1238150632, COSV100296685; called by muse, mutect2, varscan2
- DENND2C | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 196/405 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0.166); catalogued as rs887055482; called by muse, mutect2, varscan2
- EPB41L2 | c.2320G>A p.E774K | Missense Mutation (SNP) | VAF 38/512 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as rs1458721147, COSV100440697; called by muse, mutect2
- GAS8 | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 139/297 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.131); catalogued as rs537083866, COSV51946366; called by muse, mutect2, varscan2
- HEG1 | c.2834G>T p.G945V | Missense Mutation (SNP) | VAF 201/391 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs748985820; called by muse, mutect2, varscan2
- HNF1A | c.154G>A p.G52S | Missense Mutation (SNP) | VAF 394/846 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs769666514; called by muse, mutect2, varscan2
- HTR4 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 46/355 reads (13%) | catalogued as rs1271130452; called by muse, mutect2, varscan2
- KBTBD13 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 377/835 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); catalogued as rs1403660333; called by muse, mutect2, varscan2
- NPAS3 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 30/301 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV58071670, COSV58113140; called by muse, mutect2, varscan2
- PACS2 | c.585G>A p.T195= | Splice Region (SNP) | VAF 197/387 reads (51%) | catalogued as rs782662452; called by muse, mutect2, varscan2
- PCDHGA7 | c.1880G>A p.R627H | Missense Mutation (SNP) | VAF 266/562 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.643); catalogued as rs1252058358, COSV53938000, COSV99535011; called by muse, mutect2, varscan2
- RHBDD1 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 262/545 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773433822, COSV58125871; called by muse, mutect2, varscan2
- SLITRK3 | c.561G>T p.M187I | Missense Mutation (SNP) | VAF 170/349 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV53845941; called by muse, mutect2, varscan2
- STAG2 | c.190C>A p.P64T | Missense Mutation (SNP) | VAF 48/298 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV54352790; called by muse, mutect2, varscan2
- TMTC1 | c.503C>T p.A168V (on ENST00000539277 / NM_001193451.2; = p.A60V on NM_175861.3) | Missense Mutation (SNP) | VAF 27/440 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs773111431, COSV104372517, COSV55477225; called by muse, mutect2
- TRIML2 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 30/366 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0.331); catalogued as rs1202011469, COSV100456425; called by muse, mutect2
- USH2A | c.206G>C p.S69T | Missense Mutation (SNP) | VAF 155/331 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as CM1310705; called by muse, mutect2, varscan2
- VWC2L | c.513C>A p.C171* | Nonsense Mutation (SNP) | VAF 19/235 reads (8%) | catalogued as COSV100434988, COSV100435375; called by muse, mutect2
- ZNF624 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 20/472 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.359); catalogued as COSV60938965, COSV60940752; called by muse, mutect2
- AGRN | c.3490G>T p.E1164* | Nonsense Mutation (SNP) | VAF 82/284 reads (29%) | called by muse, mutect2, varscan2
- ANKRD2 | c.66G>T p.W22C | Missense Mutation (SNP) | VAF 337/771 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAMSAP1 | c.3895G>A p.E1299K | Missense Mutation (SNP) | VAF 354/741 reads (48%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DHX36 | c.1414dup p.L472Pfs*35 | Frame Shift Ins (INS) | VAF 145/362 reads (40%) | called by mutect2, pindel, varscan2
- ETV6 | c.486dup p.R163Qfs*6 | Frame Shift Ins (INS) | VAF 60/489 reads (12%) | called by mutect2, pindel, varscan2
- ETV6 | c.719T>C p.M240T | Missense Mutation (SNP) | VAF 103/833 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- FPR2 | c.895C>G p.P299A | Missense Mutation (SNP) | VAF 54/450 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GP2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 162/339 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- H4C7 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 150/339 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- LRRC9 | c.2229G>C p.L743F | Missense Mutation (SNP) | VAF 38/258 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- MAGI3 | c.913_914insGGTTTACTG p.T304_D305insGFT | In Frame Ins (INS) | VAF 53/385 reads (14%) | called by mutect2, pindel, varscan2
- MDN1 | c.10915_10916insTT p.W3639Ffs*30 | Frame Shift Ins (INS) | VAF 211/569 reads (37%) | called by mutect2, pindel, varscan2
- MSH4 | c.1948T>G p.W650G | Missense Mutation (SNP) | VAF 110/286 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- NPL | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 122/249 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRXN1 | c.3480G>C p.Q1160H | Missense Mutation (SNP) | VAF 82/580 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- SLITRK4 | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 57/190 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UGGT2 | c.4213G>C p.A1405P | Missense Mutation (SNP) | VAF 30/280 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANTXR1 | c.753C>T p.N251= | Silent (SNP) | VAF 65/390 reads (17%) | catalogued as rs141202830; called by muse, mutect2, varscan2
- CD200R1 | c.381C>T p.D127= (on ENST00000471858 / NM_170780.3; = p.D150= on NM_138806.4) | Silent (SNP) | VAF 211/447 reads (47%) | catalogued as rs373257099; called by muse, mutect2
- COL1A1 | c.3540C>T p.P1180= | Silent (SNP) | VAF 266/570 reads (47%) | catalogued as rs146016027, CD1110814; called by muse, mutect2, varscan2
- MARCHF1 | c.129G>A p.G43= | Silent (SNP) | VAF 33/250 reads (13%) | called by muse, mutect2, varscan2
- MMRN2 | c.1623C>T p.D541= | Silent (SNP) | VAF 376/782 reads (48%) | catalogued as rs1179516493; called by muse, mutect2, varscan2
- PIGZ | c.1281C>T p.F427= | Silent (SNP) | VAF 84/667 reads (13%) | catalogued as rs200188723; called by muse, mutect2, varscan2
- SVEP1 | c.6978G>A p.P2326= | Silent (SNP) | VAF 49/395 reads (12%) | catalogued as rs543043187, COSV99929060; called by muse, mutect2, varscan2
- TMPRSS5 | c.57C>T p.G19= | Silent (SNP) | VAF 70/528 reads (13%) | called by muse, mutect2
- DCHS2 | n.8612C>A | RNA (SNP) | VAF 254/519 reads (49%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+3137T>C | Intron (SNP) | VAF 319/629 reads (51%) | called by muse, mutect2, varscan2
- ZNF462 | c.6013-146G>A | Intron (SNP) | VAF 46/552 reads (8%) | catalogued as rs941263832; called by muse, mutect2
